Somatic mutation profile of tumor specimen MP2PRT-PAVAWY-TMP1-A (aliquot MP2PRT-PAVAWY-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVAWY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,582 days).
Specimen MP2PRT-PAVAWY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76a1547b-fd2e-4c4b-87dc-a28ab1e139a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAWY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAWY-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/777f9681-934c-4864-9511-200e0ee796e6

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/392 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFHR1 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 81/495 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.966); catalogued as COSV57626948; called by muse, mutect2, varscan2
- CLDN23 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 275/695 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV67731427; called by muse, mutect2, varscan2
- JMJD1C | c.4723G>A p.V1575I | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1483418385, COSV59514642; called by muse, mutect2, varscan2
- PODN | c.157C>T p.R53W (on ENST00000395871; = p.R5W on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 335/801 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs368513358; called by muse, mutect2, varscan2
- SHISA6 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 43/637 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs780479705; called by muse, mutect2
- EPRS1 | c.2966C>G p.P989R | Missense Mutation (SNP) | VAF 182/465 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714682 TCTCTCGCACAGTAATA>AAGG | Missense Mutation (DEL) | VAF 66/200 reads (33%) | called by pindel, varscan2*
- IGHV3-53 | chr14:106592666 del CCTCACTGTGTCTCTCGCACAGTAATACACGGCCGT | Missense Mutation (DEL) | VAF 60/159 reads (38%) | called by mutect2, pindel*, varscan2
- IGLV4-69 | c.357_359delinsCGGG p.*120Gfs*? | Frame Shift Ins (INS) | VAF 60/223 reads (27%) | called by pindel, varscan2*
- RGS11 | c.534C>A p.D178E (on ENST00000397770 / NM_183337.3; = p.D157E on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/570 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- VWA5B1 | c.393C>G p.N131K | Missense Mutation (SNP) | VAF 95/558 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZFHX4 | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 59/408 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FAT1 | c.201G>A p.A67= | Silent (SNP) | VAF 192/584 reads (33%) | catalogued as rs761403385, COSV71674357; called by muse, mutect2, varscan2
- NFATC4 | c.1683C>T p.G561= | Silent (SNP) | VAF 233/611 reads (38%) | catalogued as rs369520588; called by muse, mutect2, varscan2
- WDR90 | c.3531G>T p.S1177= | Silent (SNP) | VAF 188/486 reads (39%) | catalogued as rs369533979; called by muse, mutect2, varscan2
- IL17RE | c.1297-41A>G | Intron (SNP) | VAF 183/438 reads (42%) | called by muse, mutect2, varscan2
- POR | c.*223A>T | 3'UTR (SNP) | VAF 137/338 reads (41%) | called by muse, mutect2, varscan2
